Surgical pathology report (de-identified scan), TCGA case TCGA-37-3789, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-3789-01A (Primary Tumor).

[page 1 of 4]
Index				
1				

[page 2 of 4]
TCGA-37-3789

		Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
		Primary	Tumor	Tissue	OCT	block	1	n/a
		n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
TCGA-37-3789

Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Squamous cell carcinoma	2	2	0	x	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	over 50
n/a	n/a

Source: NCI Genomic Data Commons file b495cada-adb8-4cd5-9d16-6bfa409a789b (TCGA-37-3789.9051358F-5B74-4F6C-B7F2-FC83E8F43306.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).